Gene-level copy-number profile of tumor specimen ALCH-B3GW-TTP1-A from ALCHEMIST case ALCH-B3GW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,098 days).
Specimen ALCH-B3GW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8404f92a-9870-47b5-b272-65204881504b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,269 have no estimate.
https://portal.gdc.cancer.gov/files/28925ec4-967a-445b-bace-dcfb71fa74fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 366; copy number 2: 56,275; copy number 3: 1,531; copy number 4: 154; copy number 5: 23; copy number 8: 1; copy number 15: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:112,086,335–112,409,134, 10 genes, copy number 5: C3orf52, MIR567, GCSAM, TBILA, SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1.
- chr5:10,337,277–10,472,029, 6 genes, copy number 5: Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L.
- chr13:112,313,467–112,331,225, 2 genes, copy number 5: LINC01043, LINC01044.
- chr16:33,802,764–33,803,217, 1 gene, copy number 5: IGHV3OR16-12.
- chr20:57,648,392–57,712,780, 2 genes, copy number 5: PMEPA1, NKILA.
- chr21:8,603,547–8,680,934, 2 genes, copy number 5: RPSAP68, CR381572.2.
- chr21:43,414,483–43,427,131, 1 gene, copy number 15: SIK1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 8–20: LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
